Somatic mutation profile of tumor specimen 0DFBLQ from CCDI case PBBRKJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 5.9 years (2,161 days).
Specimen 0DFBLQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 972af531-cf02-45ff-a560-d92ee12faee7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFBL8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e305850-88e8-452c-ab90-ec15ef8a39f8

The open-access MAF lists 99 somatic variants for this specimen: 58 protein-altering or splice-affecting, 22 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 22, Intron 13, Nonsense Mutation 4, Splice Site 3, 3'UTR 2, 5'UTR 2, Frame Shift Del 1, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL1 | c.13C>G p.R5G | Missense Mutation (SNP) | VAF 30/1180 reads (3%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.01); catalogued as COSV99443730; called by muse, mutect2
- AGT | c.1277A>G p.N426S | Missense Mutation (SNP) | VAF 150/398 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV64184559; called by muse, mutect2, varscan2
- ATP8B1 | c.3596G>A p.R1199H | Missense Mutation (SNP) | VAF 69/461 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as rs543858152; called by muse, mutect2, varscan2
- DNAH8 | c.3388C>T p.R1130C | Missense Mutation (SNP) | VAF 132/1534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368700966; called by muse, mutect2
- GRID2 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 176/804 reads (22%) | catalogued as COSV56240908; called by muse, mutect2, varscan2
- IDH3A | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 103/333 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1232666947, COSV55113857; called by mutect2, varscan2
- LRRC6 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 46/1064 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs1480173229, COSV51541510; called by muse, mutect2
- LRRTM1 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.38); catalogued as COSV54438592, COSV54446043; called by muse, mutect2, varscan2
- MAP7D2 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 56/897 reads (6%) | catalogued as COSV65526028; called by muse, mutect2
- MGAT5 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 440/1089 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as rs759218169, COSV56098328; called by muse, mutect2, varscan2
- NAXD | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.459); catalogued as rs1290048682, COSV57286429, COSV57290662; called by muse, mutect2
- PIGO | c.2855-5G>A | Splice Region (SNP) | VAF 25/349 reads (7%) | catalogued as rs1370233506; called by muse, mutect2
- PPP4R4 | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 33/722 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58558100; called by muse, mutect2
- ROBO4 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 116/652 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs374471211; called by muse, mutect2, varscan2
- SYNE1 | c.430C>A p.Q144K (on ENST00000367255 / NM_182961.4; = p.Q151K on NM_033071.3) | Missense Mutation (SNP) | VAF 471/1238 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.655); catalogued as rs779465357; called by muse, mutect2, varscan2
- TMEM127 | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 244/578 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1060500598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRHDE | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 201/754 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs367558141, COSV99672037; called by muse, mutect2, varscan2
- USP12 | c.1043A>T p.Y348F | Missense Mutation (SNP) | VAF 158/865 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs751517479; called by muse, mutect2, varscan2
- YY1 | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 188/677 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51764146; called by mutect2, varscan2
- ABCC9 | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 261/1607 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADAMTS20 | c.5162A>G p.K1721R | Missense Mutation (SNP) | VAF 38/678 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.029); called by muse, mutect2
- ARHGEF5 | c.2734A>T p.T912S | Missense Mutation (SNP) | VAF 86/391 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATRX | c.4357G>T p.E1453* | Nonsense Mutation (SNP) | VAF 345/410 reads (84%) | called by muse, mutect2, varscan2
- BMS1 | c.1487T>C p.M496T | Missense Mutation (SNP) | VAF 99/1579 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- C4orf54 | c.3260T>A p.F1087Y | Missense Mutation (SNP) | VAF 103/581 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 21/894 reads (2%) | called by muse, mutect2
- CCDC175 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 52/1078 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2
- CWC27 | c.248T>A p.F83Y | Missense Mutation (SNP) | VAF 70/1322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EGFR | c.1548G>C p.W516C | Missense Mutation (SNP) | VAF 1594/13570 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FPGT-TNNI3K | c.981G>T p.L327F | Missense Mutation (SNP) | VAF 51/2206 reads (2%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2
- FSIP2 | c.1079-1G>T p.X360_splice | Splice Site (SNP) | VAF 33/1097 reads (3%) | called by muse, mutect2
- GDF10 | c.552G>C p.Q184H | Missense Mutation (SNP) | VAF 20/648 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- GPR26 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 107/235 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GPR50 | c.1582C>T p.H528Y | Missense Mutation (SNP) | VAF 281/320 reads (88%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC2 | c.242_243dup p.P82Dfs*43 | Frame Shift Ins (INS) | VAF 370/971 reads (38%) | called by mutect2, varscan2
- KIAA1109 | c.12690C>G p.S4230R | Missense Mutation (SNP) | VAF 427/1143 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LMO2 | c.245G>C p.R82T (on ENST00000395833 / NM_001142315.2; = p.R151T on NM_005574.4) | Missense Mutation (SNP) | VAF 42/551 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2
- MAGEB2 | c.200C>A p.T67N | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- MBD5 | c.2789A>G p.Q930R | Missense Mutation (SNP) | VAF 114/1736 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- MROH2A | c.1483T>A p.L495M | Missense Mutation (SNP) | VAF 289/759 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- NIBAN1 | c.601+1G>C p.X201_splice | Splice Site (SNP) | VAF 259/600 reads (43%) | called by muse, mutect2, varscan2
- NUP214 | c.3937C>G p.P1313A | Missense Mutation (SNP) | VAF 96/1864 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2
- NWD1 | c.4471A>G p.T1491A | Missense Mutation (SNP) | VAF 236/784 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NYAP1 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 26/816 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- OR4C6 | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 350/920 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- OR51S1 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 56/549 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- PAM | c.2331+1G>T p.X777_splice | Splice Site (SNP) | VAF 78/1119 reads (7%) | called by muse, mutect2
- PANX1 | c.1065G>T p.K355N | Missense Mutation (SNP) | VAF 54/1096 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2
- PSAT1 | c.819C>G p.I273M | Missense Mutation (SNP) | VAF 32/1230 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2
- RNASEL | c.1951del p.R651Efs*13 | Frame Shift Del (DEL) | VAF 368/900 reads (41%) | called by mutect2, varscan2
- SERPINB11 | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 496/643 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC28A1 | c.1742T>C p.L581P | Missense Mutation (SNP) | VAF 96/495 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC9A2 | c.1283A>G p.D428G | Missense Mutation (SNP) | VAF 40/1212 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- THOC1 | c.1697A>T p.D566V | Missense Mutation (SNP) | VAF 52/1528 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.073); called by muse, mutect2
- TRIM22 | c.1103T>A p.I368N | Missense Mutation (SNP) | VAF 106/1225 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- USH1G | c.620A>G p.H207R | Missense Mutation (SNP) | VAF 44/670 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.038); called by muse, mutect2
- VPS54 | c.1517C>G p.T506R | Missense Mutation (SNP) | VAF 48/1426 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.055); called by muse, mutect2
- VWC2L | c.356A>T p.H119L | Missense Mutation (SNP) | VAF 523/1271 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AFF2 | c.2610C>G p.R870= | Silent (SNP) | VAF 30/322 reads (9%) | called by muse, mutect2
- ARL6IP1 | c.541T>C p.L181= | Silent (SNP) | VAF 94/1427 reads (7%) | called by muse, mutect2
- ASMTL | c.1290G>C p.R430= | Silent (SNP) | VAF 48/635 reads (8%) | called by muse, mutect2
- CCDC185 | c.138C>T p.A46= | Silent (SNP) | VAF 106/401 reads (26%) | catalogued as COSV64821045; called by muse, mutect2, varscan2
- CYP4F22 | c.117G>T p.L39= | Silent (SNP) | VAF 45/505 reads (9%) | called by muse, mutect2
- ENPP5 | c.606G>A p.P202= | Silent (SNP) | VAF 309/866 reads (36%) | catalogued as rs759446762; called by muse, mutect2, varscan2
- FAM133A | c.87A>C p.T29= | Silent (SNP) | VAF 31/794 reads (4%) | called by muse, mutect2
- FNDC1 | c.1437A>T p.S479= | Silent (SNP) | VAF 412/1102 reads (37%) | called by muse, mutect2
- FOSB | c.270G>A p.Q90= | Silent (SNP) | VAF 149/342 reads (44%) | called by muse, mutect2, varscan2
- HECTD2 | c.801C>T p.F267= | Silent (SNP) | VAF 461/628 reads (73%) | called by muse, mutect2, varscan2
- ITGB2 | c.690G>T p.L230= | Silent (SNP) | VAF 94/1896 reads (5%) | called by muse, mutect2
- ONECUT2 | c.1353G>A p.P451= | Silent (SNP) | VAF 225/301 reads (75%) | catalogued as rs771463396, COSV72153377; called by muse, mutect2, varscan2
- OR5P3 | c.768C>T p.T256= | Silent (SNP) | VAF 26/682 reads (4%) | catalogued as COSV60429424; called by muse, mutect2
- PCLO | c.3492A>G p.V1164= | Silent (SNP) | VAF 52/2256 reads (2%) | catalogued as COSV61635512, COSV61649401; called by muse, mutect2
- PROKR2 | c.513C>G p.S171= | Silent (SNP) | VAF 56/1260 reads (4%) | called by muse, mutect2
- RAB44 | c.1914C>T p.G638= | Silent (SNP) | VAF 66/278 reads (24%) | catalogued as rs936589290; called by muse, mutect2, varscan2
- RAP2B | c.474C>A p.A158= | Silent (SNP) | VAF 216/600 reads (36%) | called by muse, mutect2, varscan2
- SH2D3C | c.282C>T p.A94= | Silent (SNP) | VAF 133/1007 reads (13%) | called by muse, mutect2, varscan2
- SIRPB1 | c.844C>T p.L282= | Silent (SNP) | VAF 258/659 reads (39%) | called by muse, mutect2, varscan2
- STYXL2 | c.1944G>C p.A648= | Silent (SNP) | VAF 164/436 reads (38%) | catalogued as COSV54801549; called by muse, mutect2, varscan2
- ZNF468 | c.444G>C p.L148= | Silent (SNP) | VAF 364/1026 reads (35%) | called by muse, mutect2
- ZNF521 | c.2451C>A p.A817= | Silent (SNP) | VAF 66/1012 reads (7%) | catalogued as COSV64126537; called by muse, mutect2
- ABLIM3 | c.*1050G>T | 3'UTR (SNP) | VAF 26/100 reads (26%) | catalogued as rs1319285568; called by mutect2, varscan2
- AC011503.1 | n.467+8676C>T | Intron (SNP) | VAF 50/875 reads (6%) | catalogued as rs775135497; called by muse, mutect2
- ADAM33 | c.600+100T>C | Intron (SNP) | VAF 9/84 reads (11%) | catalogued as rs942085418; called by muse, mutect2
- APC2 | c.-15C>T | 5'UTR (SNP) | VAF 62/539 reads (12%) | catalogued as rs944612719; called by muse, mutect2, varscan2
- CEACAM3 | c.-48A>T | 5'UTR (SNP) | VAF 21/233 reads (9%) | called by muse, mutect2
- DERL2 | c.93+93G>A | Intron (SNP) | VAF 8/119 reads (7%) | catalogued as rs1351238512; called by muse, mutect2
- DNAJC8 | c.304+83C>G | Intron (SNP) | VAF 31/323 reads (10%) | called by muse, mutect2
- FAM177B | c.241+55G>A | Intron (SNP) | VAF 156/351 reads (44%) | called by muse, mutect2, varscan2
- FAM83G | chr17:18970961 G>T | 3'Flank (SNP) | VAF 22/27 reads (81%) | catalogued as COSV58761893; called by muse, mutect2, varscan2
- ILKAP | c.299-10T>C | Intron (SNP) | VAF 86/1383 reads (6%) | called by muse, mutect2
- LHFPL6 | c.*64A>C | 3'UTR (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- MCC | c.2085+26C>G | Intron (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- MUC6 | c.7142+42T>G | Intron (SNP) | VAF 40/135 reads (30%) | called by muse, mutect2
- NAALADL1 | c.1078+69G>T | Intron (SNP) | VAF 42/229 reads (18%) | called by muse, mutect2, varscan2
- PCSK4 | c.855+32C>T | Intron (SNP) | VAF 36/424 reads (8%) | called by muse, mutect2
- SGK1 | chr6:134177701 C>T | 5'Flank (SNP) | VAF 148/807 reads (18%) | catalogued as rs376372298; called by muse, mutect2, varscan2
- SYCP1 | c.801+55C>G | Intron (SNP) | VAF 101/442 reads (23%) | called by muse, mutect2, varscan2
- TNRC6A | c.4122+42del | Intron (DEL) | VAF 48/158 reads (30%) | catalogued as rs773383340; called by mutect2, varscan2
- TRMT6 | c.1112+12G>T | Intron (SNP) | VAF 64/786 reads (8%) | called by muse, mutect2
